FM case AD13200 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/2249a3e5-1a71-4fef-8afc-6b1f673e28f2

Female, 65.5 years: Acinar cell carcinoma (ICD-O-3 8550/3) of the pancreas; primary biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
